TARGET case TARGET-30-PALAKM — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97bec9f6-e628-536d-b38b-ba28a1159fce

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 2,846 days (7.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.1; Tissue or organ of origin: Medulla of adrenal gland; Classification of tumor: primary; Age at diagnosis: 4.8 years (1,758 days); Year of diagnosis: 2001; Days to last follow up: 2,846 days (7.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 2,820 days (7.7 years); Progression or recurrence anatomic site: Mediastinum, NOS; Days to first event: 2,820 days (7.7 years); First event: Relapse.
- Days to follow up: 2,846 days (7.8 years); Year of follow up: 2009.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PALAKM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALAKM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2846
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.06
- Histology: Unfavorable
- MKI: Low
- Site of Relapse: Other, specify: Right chest and mediastinum
- Relapse Percent Tumor: 90
- Relapse Percent Necrosis: 10
- Relapse Percent Tumor v/s Stroma: >90/<10
